Gene-level copy-number profile of tumor specimen TCGA-KP-A3VZ-01A from TCGA case TCGA-KP-A3VZ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 69.4 years (25,366 days).
Specimen TCGA-KP-A3VZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.0238f14f-917b-4c02-a59f-518665e5afce.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KP-A3VZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 829 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1b2163c5-70c5-4f4e-865b-8eecbb40c1c9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 4,422; copy number 2: 22,213; copy number 3: 20,626; copy number 4: 9,165; copy number 5: 1,701; copy number 6: 781; copy number 7: 502; copy number 8: 48; copy number 10: 272; copy number 11: 42.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KP-A3VZ-01A-11D-A227-01): tumor purity 0.94, ploidy 2.8, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:128,039,135–128,204,383, 10 genes (within-gene range 0–1): AL360268.2, NAIF1, SLC25A25, AL360268.1, SLC25A25-AS1, PTGES2, PTGES2-AS1, LCN2, C9orf16, CIZ1.
- chr16:3,365,099–3,479,550, 1 gene (within-gene range 0–1): AC025283.2.
- chr16:3,401,215–3,486,953, 3 genes (within-gene range 0–1): ZNF174, ZNF597, NAA60.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,346 genes in 30 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:110,347,116–110,443,817, 1 gene, copy number 5 (within-gene range 3–5): LAMTOR5-AS1.
- chr1:110,401,249–111,041,925, 21 genes, copy number 5: LAMTOR5, PROK1, AL358215.1, AL358215.2, AL358215.3, CYMP, CYMP-AS1, KCNA10, KCNA2, AL365361.1, KCNA3, Y_RNA, NRBF2P3, OR11I1P, CD53, AL360270.2, AL360270.1, LRIF1, AL360270.3, CCNT2P1, RNA5SP54.
- chr1:156,061,160–156,243,332, 8 genes, copy number 6 (within-gene range 3–6): RAB25, MEX3A, LMNA, SEMA4A, AL135927.1, SLC25A44, PMF1-BGLAP, PMF1.
- chr2:48,809,340–49,419,013, 1 gene, copy number 5 (within-gene range 4–5): AC009975.1.
- chr2:49,202,126–52,961,452, 30 genes, copy number 5: AC009975.2, RNU6-439P, AC009971.1, RPL7P13, SNORA75, NRXN1, AC068725.1, MTCO1P42, AC009234.1, MIR8485, AC007560.1, AC007682.1, AC007402.1, AC007402.2, KNOP1P3, CRYGGP, AC097463.1, CCDC12P1, AC079304.1, ZNF863P, Y_RNA, LINC01867, GGCTP3, AC139712.1, CRTC1P1, FTH1P6, MIR4431, AC010967.1, AC010967.2, AC010967.3.
- chr2:75,710,782–84,040,720, 72 genes, copy number 5 (broad region; genes not listed).
- chr2:112,817,076–114,007,304, 49 genes, copy number 5 (within-gene range 4–5): AC079753.2, IL1B, AC079753.1, XIAPP3, IL37, CDK8P2, IL36G, HMGN2P23, POLR2DP1, IL36A, IL36B, IL36RN, IL1F10, RNU6-1180P, IL1RN, PSD4, AC016683.1, PAX8-AS1, PAX8, AC016745.1, IGKV1OR2-108, AC016745.2, CBWD2, FOXD4L1, LINC01961, PGM5P4-AS1, PGM5P4, FAM138B, AL078621.2, MIR1302-3, WASH2P, DDX11L2, AL078621.1, RPL23AP7, RABL2A, SNRPA1P1, ACRP1, AC017074.2, AC017074.1, RNU6-744P, SLC35F5, MIR4782, AC104653.2, AC104653.1, AC110769.2, ACTR3, AC110769.3, LINC01191, AC110769.1.
- chr2:163,593,396–172,109,982, 106 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr2:172,234,230–172,237,223, 1 gene, copy number 5: AC104088.3.
- chr2:173,075,435–182,523,192, 179 genes, copy number 5 (broad region; genes not listed).
- chr2:234,682,668–235,178,905, 7 genes, copy number 5: LINC01173, AC104394.1, AC010148.1, SH3BP4, AC114814.1, CEP19P1, AC114814.2.
- chr2:235,505,751–235,507,566, 1 gene, copy number 5: AGAP1-IT1.
- chr3:161,324,913–198,222,513, 654 genes, copy number 5–6 (broad region; genes not listed).
- chr5:58,198–31,329,146, 460 genes, copy number 5–6 (broad region; genes not listed).
- chr6:152,091,712–152,637,801, 4 genes, copy number 5 (within-gene range 4–5): AL078582.2, AL078582.1, SYNE1, SYNE1-AS1.
- chr9:60,914,407–73,579,498, 240 genes, copy number 5–6 (broad region; genes not listed).
- chr10:124,801,819–131,311,721, 82 genes, copy number 5 (broad region; genes not listed).
- chr12:18,080,869–34,249,958, 293 genes, copy number 5 (broad region; genes not listed).
- chr14:81,169,776–81,743,749, 14 genes, copy number 5: AL136040.2, GTF2A1, SNORA79, AL136040.1, DYNLL1P1, UNGP3, STON2, AL121769.1, DYNLL1P2, LINC02308, SEL1L, LINC01467, EEF1A1P2, LINC02311.
- chr14:81,777,016–81,777,613, 1 gene, copy number 5: RPL9P6.
- chr17:52,390,515–54,478,168, 13 genes, copy number 5: LINC01982, LINC02089, LINC02876, MTCO1P40, AC034268.2, AC005341.1, AC090079.1, AC090079.2, AC034268.1, RPS2P48, KIF2B, AC023934.1, ISCA1P3.
- chr19:94,062–975,939, 60 genes, copy number 7: OR4G3P, OR4G1P, OR4F17, WBP1LP11, OR4F8P, AC092192.1, SEPTIN14P19, CICP19, AC092299.1, AC010507.1, LINC01002, AC010507.2, RNU6-1076P, AC016588.2, PLPP2, MIER2, AC016588.1, THEG, AC010641.2, AC010641.1, C2CD4C, SHC2, RNA5SP462, ODF3L2, MADCAM1, AC005775.1, TPGS1, CDC34, GZMM, AC009005.1, BSG, HCN2, AC005559.1, POLRMT, AC004449.1, FGF22, RNF126, AC004156.1, FSTL3, PRSS57, RPS2P52, PALM, MISP, AC006273.1, LINC01836, PTBP1, MIR4745, PLPPR3, MIR3187, AZU1, PRTN3, ELANE, CFD, MED16, RNU6-9, R3HDM4, KISS1R, ARID3A, AC005379.1, AC005391.1.
- chr19:9,560,329–16,197,738, 393 genes, copy number 7 (broad region; genes not listed).
- chr19:27,638,483–28,727,680, 25 genes, copy number 7 (within-gene range 2–7): ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1.
- chr19:29,287,011–36,498,159, 249 genes, copy number 7–11 (within-gene range 2–11) (broad region; genes not listed).
- chr19:37,217,926–38,587,564, 56 genes, copy number 10 (within-gene range 2–10): ZNF383, AC016590.1, LINC01535, AC016590.4, ZNF875, AC016590.3, AC016590.2, ZNF527, AC008806.1, ZNF569, ZNF570, ZNF793-AS1, AC022148.2, ZNF793, AC022148.1, ZNF571-AS1, ZNF540, ZNF571, ZFP30, ZNF781, AC093227.2, SELENOKP1, ZNF607, AC093227.1, AC093227.3, ZNF573, AC016582.2, AC016582.3, AC016582.1, WDR87, SIPA1L3, AC008395.1, AC011465.1, AC011479.3, AC011479.2, RN7SL663P, DPF1, SPINT2, PPP1R14A, AC011479.1, AC011479.4, Y_RNA, YIF1B, C19orf33, KCNK6, CATSPERG, AC005625.1, PSMD8, GGN, AC005789.1, SPRED3, FAM98C, RASGRP4, RYR1, AC067969.2, AC067969.1.
- chr19:38,836,388–39,846,379, 68 genes, copy number 10 (within-gene range 2–10) (broad region; genes not listed).
- chr19:47,428,017–47,865,459, 24 genes, copy number 5–11: SLC8A2, AC073548.2, KPTN, NAPA-AS1, NAPA, AC073548.1, ZNF541, RN7SL322P, AC010519.1, AC010331.1, BICRA, BICRA-AS1, AC008985.1, EHD2, NOP53, SNORD23, NOP53-AS1, SELENOW, RPL23AP80, AC008745.1, TPRX1, CRX, TPRX2P, LINC01595.
- chr20:346,782–10,434,222, 227 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr21:19,244,543–19,760,128, 7 genes, copy number 5: SLC6A6P1, AP000855.1, RNU1-139P, RPL37P4, NIPA2P3, SREK1IP1P1, C1QBPP1.

Autosomal genes at a single copy (total copy number 1): 3,518. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
